Somatic mutation profile of tumor specimen MP2PRT-PASIVR-TMP1-A (aliquot MP2PRT-PASIVR-TMP1-A-1-0-D-A81N-36) from MP2PRT case MP2PRT-PASIVR, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.5 years (917 days).
Specimen MP2PRT-PASIVR-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 75ed520c-7a09-4e07-9199-ef429513617c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASIVR-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASIVR-NB1-A-1-0-D-A81N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/befcb6d3-54d9-4e85-978a-b25a09b1e798

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Nonsense Mutation 1, 3'Flank 1, Frame Shift Ins 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CD207 | c.10G>T p.E4* | Nonsense Mutation (SNP) | VAF 110/287 reads (38%) | catalogued as COSV69652271; called by muse, mutect2, varscan2
- DAND5 | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 131/366 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs748806881, COSV57684082; called by muse, mutect2, varscan2
- NEBL | c.301G>A p.V101I | Missense Mutation (SNP) | VAF 22/370 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as rs779226177; called by muse, mutect2
- C11orf54 | c.775G>A p.G259R (on ENST00000331239; = p.G209R on NM_014039.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PKHD1 | c.8359G>T p.G2787W | Missense Mutation (SNP) | VAF 133/420 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRAMEF20 | c.94C>G p.P32A | Missense Mutation (SNP) | VAF 26/459 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TRRAP | c.7804_7805insGT p.L2602Rfs*5 (on ENST00000359863 / NM_001244580.1; = p.L2584Rfs*5 on NM_003496.3) | Frame Shift Ins (INS) | VAF 91/303 reads (30%) | called by mutect2, pindel, varscan2
- USP35 | c.1152C>T p.F384= | Silent (SNP) | VAF 59/377 reads (16%) | catalogued as COSV71572612, COSV71572763; called by muse, mutect2, varscan2
- IGKV1OR2-108 | chr2:113406872 ins CC | 3'Flank (INS) | VAF 13/124 reads (10%) | called by mutect2, pindel, varscan2
